Surgical pathology report (de-identified scan), TCGA case TCGA-86-6562, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-6562-01A (Primary Tumor).

LUNG TISSUE CHECKLIST

Specimen type: Pneumonectomy

Tumor site: Lung

Tumor size: 3 x 2.5 x 2 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Poorly differentiated

Tumor extent: Not specified

Other tumor nodules: Not specified

Lymph nodes: 2/12 positive for metastasis (Hilar 2/12)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Source: NCI Genomic Data Commons file 36ee4507-6d66-4f10-86f8-5746fb435050 (TCGA-86-6562.B0E49AC9-6B9C-4E70-A4A9-10E0686E61AA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).